CPTAC case C3N-06046 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b42f039-e9ca-4f1e-ae33-e3656e5530eb

Demographics
Sex at birth: male; Race: white; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 254 days; Year of death: 2021; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2020; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4b; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 254 days; Progression or recurrence: no; Days to last follow up: 254 days; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 5 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 1; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: Yes.

Follow-up (2 entries)
- Days to follow up: 254 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 254 days; Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 31; Cigarettes per day: 20; Tobacco smoking onset year: 1949; Tobacco smoking quit year: 1980; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 31.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-06046-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Penis; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 132 days; Initial weight: 118 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-06046-22: Section location: Glans penis; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-06046-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Penis; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 132 days; Initial weight: 148 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-06046-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 133 days; Method of sample procurement: Blood Draw.
